Somatic mutation profile of tumor specimen TCGA-2H-A9GL-01A (aliquot TCGA-2H-A9GL-01A-12D-A37C-09) from TCGA case TCGA-2H-A9GL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 74.2 years (27,115 days).
Specimen TCGA-2H-A9GL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f02d4ad5-08bf-4601-bf2a-595817bb0886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GL-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GL-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04a982f4-7296-4c2f-8155-5f5cfdf8e423

The open-access MAF lists 217 somatic variants for this specimen: 162 protein-altering or splice-affecting, 47 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 47, Nonsense Mutation 7, Intron 4, In Frame Del 3, Frame Shift Ins 3, Frame Shift Del 3, 5'Flank 2, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.2645T>C p.F882S (on ENST00000506720 / NM_001322402.2; = p.F814S on NM_015236.6) | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV101547327; called by muse, mutect2, varscan2
- ADGRL4 | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100876351, COSV66063786, COSV66064462; called by muse, mutect2, varscan2
- ASTN2 | c.2282A>G p.K761R (on ENST00000313400 / NM_001365069.1; = p.K710R on NM_014010.5) | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs974202503, COSV100524865, COSV100531251; called by muse, mutect2, varscan2
- C6orf118 | c.790T>C p.F264L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV100025287; called by muse, mutect2, varscan2
- CELF4 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58465200; called by muse, mutect2
- CERK | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346553438; called by muse, mutect2, varscan2
- CHST13 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60042912; called by muse, varscan2
- CILP2 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs751776570, COSV52272441; called by muse, varscan2
- COL5A1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs374020067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.3772T>A p.L1258M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99241914; called by muse, mutect2, varscan2
- CTAGE1 | c.1225A>T p.K409* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV66944636; called by muse, mutect2, varscan2
- DLG2 | c.192T>G p.I64M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247938717, COSV65884465; called by muse, mutect2, varscan2
- EIF4B | c.988dup p.Q330Pfs*14 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs747252313; called by mutect2, varscan2
- ERCC6L2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs1362904914; called by muse, mutect2, varscan2
- FAM47C | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV63723950; called by muse, mutect2, varscan2
- FN3K | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV104395334; called by muse, mutect2, varscan2
- FOXN3 | c.944G>A p.R315Q (on ENST00000261302; = p.R293Q on NM_005197.4) | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.656); catalogued as rs748675321; called by muse, mutect2, varscan2
- FRY | c.2854G>T p.V952L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1309106689; called by muse, mutect2, varscan2
- GALNT7 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs768436145; called by muse, mutect2, varscan2
- GPC6 | c.323T>G p.F108C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100988534; called by muse, mutect2, varscan2
- GRPR | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246452682, COSV100977625; called by muse, mutect2
- HEATR1 | c.5629T>G p.F1877V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV63982083; called by muse, mutect2, varscan2
- JAKMIP3 | c.1508G>C p.R503P | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53821915; called by muse, mutect2, varscan2
- JPH4 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV62508275; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>C p.L966P | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- LAMA5 | c.8623G>A p.V2875I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs199704088, COSV99440337; called by muse, mutect2, varscan2
- LRRC32 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs868191441, COSV99476578; called by muse, mutect2, varscan2
- LRRIQ1 | c.3671A>T p.K1224M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV67825759, COSV67827919; called by muse, mutect2, varscan2
- MANEAL | c.1221G>C p.W407C (on ENST00000373045 / NM_001113482.1; = p.W185C on NM_152496.2) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61116767; called by muse, mutect2, varscan2
- MARCHF10 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs112642238; called by muse, mutect2, varscan2
- MEX3A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771196067, COSV64142001; called by muse, mutect2, varscan2
- MIOX | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs146378961; called by muse, mutect2, varscan2
- MMP24 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs777159332; called by muse, mutect2, varscan2
- MYH7 | c.4348G>A p.D1450N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs397516211, CM122821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1F | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 88/111 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs368617557; called by muse, mutect2, varscan2
- NRG1 | c.722A>C p.K241T (on ENST00000405005 / NM_013964.5; = p.K246T on NM_013956.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1377627153; called by muse, varscan2
- NRXN3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV55366600; called by muse, mutect2, varscan2
- OR2T33 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58817876; called by muse, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- PCDH15 | c.4523A>G p.K1508R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs755797602; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PCDHA10 | c.941C>G p.T314S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); catalogued as rs1554149390; called by muse, mutect2, varscan2
- PCNX2 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV50780665; called by muse, mutect2, varscan2
- PCP2 | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as rs1568459184; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100982449, COSV65047110; called by muse, mutect2, varscan2
- PRAMEF15 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1266149696; called by muse, varscan2
- PREX2 | c.415del p.I139* | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV55776999; called by pindel, varscan2*
- PTCHD4 | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.911); catalogued as rs746354968; called by muse, mutect2, varscan2
- SETD5 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs757905878; called by muse, mutect2, varscan2
- SGCG | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54556200, COSV54557004; called by muse, mutect2, varscan2
- SI | c.3499T>G p.L1167V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100014645, COSV52303947; called by muse, mutect2, varscan2
- SLCO4C1 | c.2044T>G p.F682V | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV60513404; called by muse, mutect2, varscan2
- SLITRK5 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV61521491, COSV61523687; called by muse, mutect2, varscan2
- SVOPL | c.511G>A p.G171S (on ENST00000419765; = p.G19S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs535345971; called by muse, mutect2, varscan2
- TNN | c.2093A>G p.K698R | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV53425748; called by muse, mutect2, varscan2
- TRAK2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as rs368306993; called by mutect2, varscan2
- ZDBF2 | c.542dup p.V182Sfs*4 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | catalogued as rs781132593; called by mutect2, pindel, varscan2
- ZNF331 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53477076; called by muse, mutect2, varscan2
- ZNF669 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV58537193; called by muse, mutect2, varscan2
- A2ML1 | c.2582T>C p.V861A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB1 | c.2498T>C p.L833P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC5 | c.1550A>T p.K517I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ABCC9 | c.3719G>T p.S1240I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABI3BP | c.1707A>C p.E569D | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC013489.1 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- ACTN2 | c.1175A>C p.E392A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADGRB2 | c.1510G>C p.A504P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- AHNAK2 | c.12685G>T p.V4229L | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ASXL3 | c.2014T>C p.F672L | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAK1 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- BBS9 | c.2638T>G p.S880A (on ENST00000242067 / NM_001348036.1; = p.S840A on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BRINP2 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- C1orf94 | c.1248A>C p.E416D (on ENST00000488417 / NM_001134734.2; = p.E226D on NM_032884.5) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC144A | c.2915T>C p.L972P | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCNA1 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CFAP74 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CLASP2 | c.3400A>T p.T1134S (on ENST00000359576; = p.T1133S on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CLCNKB | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPXM2 | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.5932A>G p.T1978A (on ENST00000520002; = p.T1977A on NM_033225.6) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CWH43 | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DCAF12L1 | c.742A>G p.R248G | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DENND5B | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DIO2 | c.662T>G p.I221R | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ERICH3 | c.4118A>G p.N1373S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ERICH3 | c.3330A>T p.R1110S | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERO1B | c.219C>G p.Y73* | Nonsense Mutation (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- ESRP1 | c.1898C>G p.T633R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM155A | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FAM214B | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- FAT3 | c.4096T>G p.F1366V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- FRMD7 | c.1289A>T p.N430I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSTL3 | c.167T>A p.V56D | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GCSAM | c.236C>G p.T79S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- GPATCH8 | c.4458C>G p.H1486Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD1B | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GRM5 | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA12A | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- IGKV1-6 | c.142A>C p.S48R | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- IL17RE | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ITGA2 | c.3362T>G p.I1121R | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- JAK1 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1549L | c.1560A>C p.E520D (on ENST00000321505; = p.E817D on NM_012194.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIF2C | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.13904A>T p.D4635V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KPNA1 | c.1406G>A p.C469Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- LANCL1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LRRC4C | c.350T>G p.I117S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2
- MAMLD1 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- MAP2 | c.5377C>T p.R1793* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- MBD5 | c.3338A>C p.Q1113P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MC4R | c.175T>G p.L59V | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.5837T>G p.V1946G | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NCOA6 | c.4828G>A p.A1610T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NDST1 | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NIPBL | c.5266A>T p.I1756F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NLGN4X | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR10X1 | c.142T>C p.F48L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4C16 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OR5AC2 | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- OR8H2 | c.846T>G p.I282M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PASD1 | c.2120A>C p.N707T | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PHLDB2 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PHOSPHO1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2
- POSTN | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM13 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2
- PRKAA1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PRKD2 | c.1782_1801del p.Q594Hfs*21 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- PTPRE | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD2 | c.587_589del p.M196del | In Frame Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- RBM10 | c.2291G>T p.C764F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.2071A>C p.T691P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SDK1 | c.4034A>G p.K1345R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINB9 | c.1095C>G p.N365K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SETBP1 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHTN1 | c.1120A>T p.M374L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SIPA1L2 | c.4718G>T p.G1573V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC1A7 | c.1440_1451del p.F481_D484del | In Frame Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- SLC39A12 | c.521A>T p.Y174F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SLC39A12 | c.1742A>T p.E581V (on ENST00000377369 / NM_001145195.2; = p.E544V on NM_152725.3) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.2635T>C p.F879L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO1C1 | c.1177T>G p.F393V | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SMAD3 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMAD6 | c.12del p.K5Nfs*59 | Frame Shift Del (DEL) | VAF 61/101 reads (60%) | called by mutect2, pindel, varscan2
- SPTA1 | c.6892T>C p.S2298P | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STARD13 | c.1960G>T p.D654Y (on ENST00000336934 / NM_001243476.3; = p.D536Y on NM_052851.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STRN4 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SYNE1 | c.5477A>G p.H1826R (on ENST00000367255 / NM_182961.4; = p.H1833R on NM_033071.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TM9SF4 | c.90_98delinsCAC p.P31_N33delinsT | In Frame Del (DEL) | VAF 13/62 reads (21%) | called by pindel, varscan2*
- TMUB2 | c.247C>T p.H83Y (on ENST00000538716 / NM_001353177.2; = p.H63Y on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TOPBP1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TP53 | c.769dup p.L257Pfs*7 | Frame Shift Ins (INS) | VAF 27/46 reads (59%) | called by mutect2, pindel, varscan2
- TRGV5 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- TTN | c.72231T>G p.S24077R (on ENST00000591111; = p.S16653R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TTN | c.71700A>C p.E23900D (on ENST00000591111; = p.E16476D on NM_003319.4) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | PolyPhen benign (0.416); called by muse, mutect2, varscan2
- UCKL1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- VPS11 | c.861G>T p.L287F (on ENST00000620429; = p.L831F on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- WDR35 | c.1546A>T p.I516L (on ENST00000345530 / NM_001006657.2; = p.I505L on NM_020779.4) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR70 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZGPAT | c.871+2T>C p.X291_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ZNF561 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 69/84 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZNF562 | c.911A>C p.N304T (on ENST00000453372 / NM_001130032.2; = p.N232T on NM_017656.4) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ADGRL4 | c.387T>G p.T129= | Silent (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13071C>A p.V4357= | Silent (SNP) | VAF 62/130 reads (48%) | called by muse, varscan2
- AP2M1 | c.246C>G p.L82= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- BBS7 | c.192G>A p.P64= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs775906320; ClinVar: likely benign; called by muse, mutect2, varscan2
- C9orf50 | c.891C>T p.S297= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs146176082; called by muse, mutect2, varscan2
- CERS2 | c.1038A>G p.T346= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- CFH | c.276T>A p.P92= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- DDX50 | c.1704C>T p.H568= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- DLG5 | c.4812G>T p.R1604= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1203C>T p.P401= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs774698555, COSV70102043; called by muse, mutect2, varscan2
- DYTN | c.1126A>C p.R376= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- FOXS1 | c.378C>T p.P126= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs949303925; called by muse, mutect2, varscan2
- GAS7 | c.852C>T p.D284= (on ENST00000432992 / NM_201433.2; = p.D144= on NM_003644.3) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs762910296; called by muse, mutect2, varscan2
- GDF5 | c.1182G>A p.K394= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.153T>G p.T51= | Silent (SNP) | VAF 126/177 reads (71%) | called by muse, mutect2, varscan2
- HBG2 | c.372C>G p.T124= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- IL5RA | c.621G>T p.G207= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- IL7R | c.1317T>G p.T439= | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- ITIH1 | c.1233G>A p.T411= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs757431575, COSV56253420, COSV56257644; called by muse, mutect2, varscan2
- IZUMO2 | c.582T>C p.S194= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- KCNV1 | c.1026T>C p.C342= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV52087362; called by muse, mutect2, varscan2
- KIF5C | c.105C>T p.G35= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV101371343; called by muse, mutect2, varscan2
- KMT2D | c.2316C>G p.P772= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs937443758; called by muse, mutect2, varscan2
- KRT6C | c.747C>G p.L249= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV52876194; called by muse, mutect2, varscan2
- KRTAP24-1 | c.6T>C p.P2= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- MAP2K5 | c.1167G>A p.S389= (on ENST00000178640 / NM_145160.3; = p.S379= on NM_002757.4) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs149823125, COSV99460298; called by muse, mutect2, varscan2
- MFSD2B | c.372C>T p.I124= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs766988877; called by muse, mutect2, varscan2
- MUC16 | c.5484A>T p.T1828= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- NLRP7 | c.1722C>T p.C574= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs779879186; called by muse, mutect2, varscan2
- OR2F1 | c.21T>C p.T7= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV67332199; called by muse, mutect2, varscan2
- PARP4 | c.5097C>T p.A1699= | Silent (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- PCGF3 | c.327G>A p.K109= | Silent (SNP) | VAF 31/38 reads (82%) | called by muse, mutect2, varscan2
- PCLO | c.9244T>C p.L3082= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- PRAMEF19 | c.903T>C p.T301= | Silent (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- PRL | c.402A>G p.Q134= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PRMT6 | c.766C>T p.L256= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- PTPRA | c.1584C>T p.T528= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- RFFL | c.156T>C p.A52= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- RIMS2 | c.3210A>G p.G1070= (on ENST00000666250 / NM_001348490.2; = p.G878= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV51695131; called by muse, mutect2, varscan2
- SIRT4 | c.627G>A p.E209= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- STPG2 | c.1353T>C p.I451= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs1373859983; called by muse, mutect2, varscan2
- SYNDIG1 | c.576C>T p.C192= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- SYNE1 | c.17091G>T p.R5697= (on ENST00000367255 / NM_182961.4; = p.R5626= on NM_033071.3) | Silent (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- WNK2 | c.6744C>T p.G2248= | Silent (SNP) | VAF 51/53 reads (96%) | catalogued as rs768523545; called by muse, mutect2, varscan2
- ZDHHC19 | c.663G>A p.S221= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- ZNF585B | c.2064A>G p.K688= | Silent (SNP) | VAF 55/72 reads (76%) | catalogued as rs1289316694; called by muse, mutect2, varscan2
- ZNF599 | c.174C>A p.I58= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500343 G>A | 5'Flank (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- CADM1 | c.1079-12115C>G | Intron (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- CTSL3P | n.361G>T | RNA (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- FSD2 | c.*3396G>A | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+5082C>T | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs565361765; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11814_3423+11817del | Intron (DEL) | VAF 22/199 reads (11%) | called by mutect2, pindel, varscan2
- RBM44 | c.-98-2821dup | Intron (INS) | VAF 44/76 reads (58%) | catalogued as rs746070623; called by mutect2, varscan2
- WT1 | chr11:32439126 C>G | 5'Flank (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2
